CCDI case PBCPBZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/ed36667c-2f0b-422b-ada7-9dfe1124f8f3

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.3 years (5,210 days).

Biospecimens (3 samples)
- Sample 0DWM0A: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWYUQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWYWJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
